Surgical pathology report (de-identified scan), TCGA case TCGA-SG-A849, project TCGA-SARC (Sarcoma), tissue source site Cleveland Clinic Foundation, specimen TCGA-SG-A849-01A (Primary Tumor).

[page 1 of 2]
Encounter Date:

Results

SURGICAL PATHOLOGY

Patient Info

Patient Name

Sex
Male

DOB

Results

Specimen #:
Submitting Physician:

FINAL DIAGNOSIS

Soft tissue mass, right anterior arm, resection

- Undifferentiated pleomorphic sarcoma with myogenic differentiation, high grade (FNCLCC grade 3 of 3).
- See comment.

COMMENT

SOFT TISSUE TUMOR

Specimen type: Resection

Site: Right anterior arm

Depth: Superficial

Size

Greatest dimension: 2.7 cm

Additional two dimensions: 2.5 x 2.0 cm

Histologic type: Undifferentiated pleomorphic sarcoma with myogenic differentiation.

Mitotic rate (per 10 HPFs): 26

Necrosis present (approximately 30%)

Pre-treatment: none

Margins: The anterior margin is focally positive for tumor. Other margins are negative for tumor; the closest uninvolved margin is the deep margin (0.4 cm).

Lymph nodes

Number examined: 0

Number positive: Not applicable

FNCLCC grade: 3 of 3

AJCC pathologic stage (pTNM)

stage: pT1a pNX

Slide A3 containing the anterior margin was compared to the paraffin block for A3 to confirm that the edge of the tissue seen on the slide is in fact the surgical margin. has reviewed the anterior margin and agrees with the interpretation that it is positive for tumor.

(Electronic Signature)

ICD-O-3
Sarcoma, undifferentiated
Pleomorphic
8802/3
Code to highest 8805/3
Site: R Arm, soft tissue C49.1
JW 10/17/13

[page 2 of 2]
Encounter Date:

SPECIMEN SUBMITTED

A: MASS RIGHT ANTERIOR ARM SARCOMA

CLINICAL DATA

MASS RIGHT UPPER ARM

LONG STITCH- PROXIMAL, SHORT STITCH- POSTERIOR, CHECK FOR MARGINS

GROSS DESCRIPTION

A. Received fresh labeled "mass right anterior arm sarcoma" is a 7.5 x 5.5 x 2.5 cm piece of soft tissue and overlying skin measuring 6.8 x 5.9 cm. It was received oriented with long stitch-proximal and short stitch-posterior. The deep surface is smooth, glistening with smooth skeletal muscle attached. The skin is grossly normal, but has firm protruding areas. There is a 2.7 x 2.5 x 2 cm mass. It is tan-white and well-demarcated from surrounding tissue. It is grossly free of all margins. It contains some areas of hemorrhage and one possible small, pinpoint area of necrosis. The distances from margins are as follows: Proximal 1.3 cm, distal 1 cm, anterior 1.5 cm, posterior 1.2 cm, deep 0.4 cm. Two photographs were taken of the mass. Tumor was given to tissue procurement and also sent for cytogenetics. Representative sections are submitted as follows: A1 distal margin, perpendicular A2 proximal margin, perpendicular A3 anterior margin and tumor, perpendicular A4 posterior margin and tumor, perpendicular A5 deep margin and tumor, perpendicular A6 tumor with possible area of necrosis, A7-A8 tumor with hemorrhagic areas.

Patient ID #:
DOB:
Date of Report:
Date of Procedure:
Date of Receipt:
Submitted by:
Location:
Test performed by:

Lab and Collection

SURGICAL PATHOLOGY

on

- Lab and Collection Information

Result History

SURGICAL PATHOLOGY

on

- Order Result History Report

Result Information

Result Date and Time

Status
Final result

Provider Status
Reviewed

Status:

This result is currently not released to

Display Full Result Report

Display Order Report

Source: NCI Genomic Data Commons file 70c49f2a-ba7d-4a26-bf43-18f3afce7e6d (TCGA-SG-A849.928D5BD3-1B13-4412-92F0-2769ADADEB04.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).